Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8060, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8060-01A (Primary Tumor).

[page 1 of 2]
Case ID		ID	Gross Description	Microscopic Description	Diagnosis Details	Comments

[page 2 of 2]
Formatted Path Report	Laterality/Location		Date of excision
STOMACH TISSUE CHECKLIST Specimen type: Excision of tumor Tumor site: Cardia Tumor size: 4 x 3 x 0.4 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Muscularis propria Lymph nodes: 4/4 positive for metastasis (Intraabdominal 4/4) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: Invades esophagus	Cardia		

Source: NCI Genomic Data Commons file 2418d94f-0cbd-49b9-b4bb-41d9828ad35d (TCGA-BR-8060.EE0F0572-9F55-45F0-8AC4-F1F846B24FD5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).